Somatic mutation profile of tumor specimen TCGA-33-AASD-01A (aliquot TCGA-33-AASD-01A-11D-A401-08) from TCGA case TCGA-33-AASD, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-33-AASD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26637939-1a76-47bf-bf4b-28e56e0281f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-AASD-11A (Solid Tissue Normal), aliquot TCGA-33-AASD-11A-11D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/670d1318-172a-46a6-b896-f4aeb497a6b8

The open-access MAF lists 406 somatic variants for this specimen: 294 protein-altering or splice-affecting, 105 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 259, Silent 105, Frame Shift Del 11, Nonsense Mutation 11, Splice Site 9, RNA 4, Intron 3, Splice Region 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HTRA1 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776873, CM108428, COSV64563405; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 19/35 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs774469695, COSV50262287, COSV50279943; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 48/53 reads (91%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.2764G>A p.A922T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99221601; called by muse, mutect2, varscan2
- ABCA3 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100068907; called by muse, mutect2, varscan2
- AC100868.1 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.919); catalogued as COSV99226555; called by muse, mutect2, varscan2
- AC126283.2 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as rs777519106, COSV101144593; called by muse, mutect2, varscan2
- ACACB | c.1406G>T p.S469I | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV100623115; called by muse, mutect2, varscan2
- ACMSD | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.009); catalogued as rs201644333, COSV51608604; called by muse, mutect2, varscan2
- ACOX2 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs749577684, COSV100250244; called by muse, mutect2, varscan2
- ACVR1B | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs753820498, COSV99231672; called by muse, varscan2
- ADGRE5 | c.134A>G p.N45S | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99663112; called by muse, mutect2, varscan2
- ADGRG7 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1198987086, COSV99841373; called by muse, mutect2, varscan2
- ADORA1 | c.951G>T p.E317D | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99704623; called by muse, mutect2, varscan2
- AGAP1 | c.2002G>T p.D668Y (on ENST00000304032 / NM_001037131.3; = p.D615Y on NM_014914.5) | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100366395; called by muse, mutect2, varscan2
- AKNAD1 | c.764A>G p.H255R | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV100645751; called by muse, mutect2, varscan2
- ALG10 | c.868C>G p.Q290E | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99848265; called by muse, mutect2, varscan2
- ANGPT2 | c.1331-2A>T p.X444_splice | Splice Site (SNP) | VAF 42/60 reads (70%) | catalogued as COSV100291077; called by muse, mutect2, varscan2
- ANK2 | c.8185G>C p.E2729Q | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.023); catalogued as COSV100001561, COSV100003077; called by muse, mutect2, varscan2
- ANO7 | c.347G>C p.W116S (on ENST00000274979; = p.W61S on NM_001001666.4) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1281692226, COSV99239010; called by muse, mutect2, varscan2
- APOB | c.2202A>T p.L734F | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99266866; called by muse, mutect2, varscan2
- ASAP2 | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV99856550; called by muse, mutect2, varscan2
- ASPM | c.1880G>C p.R627P | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99660835; called by muse, mutect2, varscan2
- ATG2A | c.2233A>T p.S745C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.237); catalogued as COSV101034629; called by muse, mutect2, varscan2
- ATRNL1 | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1442420634, COSV100746626; called by muse, mutect2, varscan2
- BECN1 | c.1028C>G p.T343R | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.295); catalogued as COSV100162160; called by muse, mutect2, varscan2
- BMP7 | c.813G>C p.Q271H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV101216142, COSV101216388; called by muse, mutect2, varscan2
- BUB1 | c.2095A>T p.R699* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100241495; called by muse, mutect2, varscan2
- C16orf78 | c.95C>G p.T32S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100147857; called by muse, mutect2, varscan2
- CALR | c.356A>G p.Q119R | Missense Mutation (SNP) | VAF 81/123 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV100330931; called by muse, mutect2, varscan2
- CARD6 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54565082; called by muse, mutect2, varscan2
- CDCA7 | c.878G>T p.R293L (on ENST00000347703 / NM_145810.3; = p.R372L on NM_031942.5) | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60720188; called by muse, mutect2, varscan2
- CDH10 | c.1397A>T p.N466I | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100052434, COSV52594282; called by muse, mutect2, varscan2
- CEP290 | c.4275A>T p.Q1425H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.58); catalogued as rs1285152017, COSV100469348, COSV58352684; called by muse, mutect2
- CEP63 | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.569); catalogued as COSV100132966; called by muse, mutect2, varscan2
- CFTR | c.984C>G p.I328M | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99138021; called by muse, mutect2, varscan2
- CHD7 | c.7946T>A p.V2649D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101418354; called by muse, mutect2, varscan2
- CNOT4 | c.1397A>T p.N466I (on ENST00000315544 / NM_001190848.1; = p.N463I on NM_013316.4) | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV100211970; called by muse, mutect2, varscan2
- CNTNAP4 | c.59G>T p.W20L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs1201561755, COSV100272517; called by muse, mutect2, varscan2
- CNTNAP4 | c.60G>T p.W20C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1245516098, COSV100272519; called by muse, mutect2, varscan2
- COG6 | c.789-2A>T p.X263_splice | Splice Site (SNP) | VAF 35/52 reads (67%) | catalogued as COSV100743156; called by muse, mutect2, varscan2
- COL14A1 | c.2563C>A p.P855T | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV99920082; called by muse, mutect2
- COL5A1 | c.3161G>A p.G1054E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100880268; called by muse, mutect2, varscan2
- COL5A3 | c.4280G>T p.G1427V | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1386927353, COSV99319400; called by muse, mutect2, varscan2
- COL8A1 | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99658145; called by muse, mutect2, varscan2
- CPED1 | c.1074C>A p.C358* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100121211; called by muse, mutect2, varscan2
- CPED1 | c.1961G>T p.G654V | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.267); catalogued as COSV100121216; called by muse, mutect2, varscan2
- CPNE5 | c.264G>C p.E88D | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99783119; called by muse, mutect2, varscan2
- CPNE6 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 61/78 reads (78%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.544); catalogued as COSV53742908, COSV53743199; called by muse, mutect2, varscan2
- CRISPLD2 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs570035929, COSV99295893; called by muse, mutect2, varscan2
- CSMD3 | c.1936A>G p.S646G (on ENST00000297405 / NM_001363185.1; = p.S542G on NM_052900.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1181595693, COSV99841834; called by muse, mutect2, varscan2
- CWH43 | c.808G>C p.A270P | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99893758; called by muse, mutect2, varscan2
- DBNL | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV101289376; called by muse, mutect2, varscan2
- DCAF13 | c.567A>G p.I189M | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs759596988, COSV99885509; called by muse, mutect2, varscan2
- DCAF4L2 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100151126, COSV60476878; called by muse, mutect2, varscan2
- DCSTAMP | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99886789; called by muse, mutect2, varscan2
- DISP3 | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.095); catalogued as rs200987282, COSV53837743, COSV99609458; called by muse, mutect2, varscan2
- DLAT | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1436678935, COSV99734888; called by muse, mutect2, varscan2
- DNAAF4 | c.405G>T p.K135N | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100336861; called by muse, mutect2, varscan2
- DNAH9 | c.2620G>C p.D874H | Missense Mutation (SNP) | VAF 61/77 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV52333376, COSV99307064; called by muse, mutect2, varscan2
- DNAJB4 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100883472; called by muse, mutect2, varscan2
- DSCAM | c.5761G>T p.D1921Y | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.365); catalogued as rs1293405371, COSV101261048; called by muse, mutect2, varscan2
- DTX3L | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1373763460, COSV99950101; called by muse, mutect2, varscan2
- DYSF | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM070077, COSV99249316; called by muse, mutect2, varscan2
- ELAVL2 | c.867G>C p.E289D | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT tolerated (0.23); PolyPhen benign (0.317); catalogued as COSV99806781; called by muse, mutect2, varscan2
- ERN2 | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99891992; called by muse, mutect2, varscan2
- F5 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.535); catalogued as rs370383592, COSV63127538; called by muse, mutect2, varscan2
- FAM135B | c.3805C>A p.Q1269K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99425947; called by muse, mutect2, varscan2
- FAM135B | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV99357124; called by muse, mutect2, varscan2
- FAM161B | c.775G>A p.E259K (on ENST00000651776; = p.E196K on NM_152445.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99679779, COSV99679880; called by muse, mutect2, varscan2
- FAT3 | c.2613G>T p.L871F | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99968376; called by muse, mutect2, varscan2
- FBN2 | c.8468C>A p.P2823H | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1157167348, COSV99329343; called by muse, mutect2, varscan2
- FBXO24 | c.1031C>T p.P344L (on ENST00000241071 / NM_033506.3; = p.P382L on NM_012172.5) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs1187670277, COSV53829645; called by muse, mutect2, varscan2
- FBXO47 | c.914T>A p.V305D | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100960807; called by muse, mutect2, varscan2
- FCRL1 | c.188C>A p.P63Q | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.037); catalogued as COSV100839849, COSV100839927; called by muse, mutect2, varscan2
- FCRL5 | c.1669C>A p.L557I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as rs1187617674, COSV100709157; called by muse, mutect2, varscan2
- FGB | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100122516; called by muse, mutect2, varscan2
- FLG | c.7243C>T p.L2415F | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as rs766035407, COSV100910899, COSV100911887; called by muse, mutect2, varscan2
- FOCAD | c.4099G>T p.A1367S | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs1187191697, COSV100620599; called by muse, mutect2, varscan2
- FRAS1 | c.10367del p.G3456Afs*3 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs1350939361; called by mutect2, pindel
- GALNT17 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.926); catalogued as COSV100355048, COSV61148982; called by muse, mutect2, varscan2
- GBE1 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV101450206, COSV70097530; called by muse, mutect2, varscan2
- GCC1 | c.1828G>T p.A610S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.272); catalogued as COSV58463800; called by muse, mutect2, varscan2
- GLRB | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234659584, COSV100029985; called by muse, mutect2, varscan2
- GPR182 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as rs779290951, COSV100267775; called by muse, mutect2, varscan2
- GPR20 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV100897367; called by muse, mutect2, varscan2
- GPR78 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs376898264; called by muse, varscan2
- GRIK1 | c.1955del p.G652Efs*9 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as COSV58729659; called by mutect2, pindel, varscan2
- GUCY1B1 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100025773; called by muse, mutect2, varscan2
- HELT | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.151); catalogued as COSV100132953, COSV58820154; called by muse, mutect2, varscan2
- HEPH | c.2324G>T p.G775V (on ENST00000343002; = p.G508V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.889); catalogued as rs765541377, COSV100295312, COSV57971126; called by muse, mutect2, varscan2
- HGF | c.131A>T p.K44I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV55958672; called by muse, mutect2
- HIPK2 | c.3380C>T p.A1127V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1449763097, COSV101301651; called by muse, mutect2, varscan2
- HOXA1 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV99761331; called by muse, mutect2, varscan2
- HSDL1 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as COSV99550445; called by muse, mutect2, varscan2
- HSPA6 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1381967152, COSV100554252; called by muse, mutect2, varscan2
- IFIH1 | c.2808-2A>T p.X936_splice | Splice Site (SNP) | VAF 26/60 reads (43%) | catalogued as rs1194779050; called by muse, mutect2
- IFIH1 | c.2044+1G>T p.X682_splice | Splice Site (SNP) | VAF 11/23 reads (48%) | catalogued as rs777846038, COSV99718755; called by muse, mutect2, varscan2
- IFIH1 | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as rs1558865869, COSV99718756; called by muse, mutect2, varscan2
- IGSF3 | c.2537T>A p.I846K (on ENST00000369486 / NM_001007237.3; = p.I866K on NM_001542.4) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100604962; called by muse, mutect2, varscan2
- IL7R | c.744G>C p.L248F | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs200086692, COSV57411421; called by muse, mutect2, varscan2
- IMPG1 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100886544; called by muse, mutect2, varscan2
- IMPG2 | c.653G>T p.R218M | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.436); catalogued as COSV99516104; called by muse, mutect2, varscan2
- ITGA1 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.62); PolyPhen benign (0.124); catalogued as COSV50886784, COSV99251828; called by muse, mutect2, varscan2
- KCNH2 | c.1634A>G p.Y545C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV100060608; called by muse, mutect2, varscan2
- KCNK9 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV100271423, COSV57288387; called by muse, mutect2, varscan2
- KCNQ3 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV101196287, COSV66467388; called by muse, mutect2, varscan2
- KIAA1549 | c.1402G>T p.V468L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54308945, COSV99651485; called by muse, mutect2, varscan2
- KIF5A | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99673330; called by muse, mutect2, varscan2
- KIFC2 | c.365G>T p.S122I | Missense Mutation (SNP) | VAF 72/138 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as rs762261187, COSV100023769; called by muse, mutect2, varscan2
- KLF8 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100808338; called by muse, mutect2, varscan2
- KLHDC7A | c.1338C>A p.N446K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762679699, COSV101272828; called by muse, mutect2, varscan2
- KLHL4 | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100910043, COSV64149571; called by muse, mutect2, varscan2
- KLRB1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV57590337, COSV99987294; called by muse, mutect2, varscan2
- KMT2A | c.5609A>G p.N1870S | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as COSV100629393; called by muse, mutect2, varscan2
- KMT2D | c.2635G>T p.E879* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as rs1385470844, COSV99982497; called by muse, mutect2, varscan2
- LHFPL3 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1163815564, COSV101308594; called by muse, mutect2, varscan2
- LIN7B | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as COSV99674553; called by muse, mutect2, varscan2
- LRP1B | c.8027-1G>C p.X2676_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as COSV101258770; called by muse, mutect2, varscan2
- LRP2 | c.3002C>A p.P1001H | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99789609; called by muse, mutect2, varscan2
- MAGI2 | c.2386G>T p.D796Y | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100835588; called by muse, mutect2, varscan2
- MED12L | c.4713G>C p.M1571I | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99854090; called by muse, mutect2, varscan2
- MFN1 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54939892; called by muse, mutect2, varscan2
- MFSD2B | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.115); catalogued as COSV100601159; called by muse, mutect2, varscan2
- MIB1 | c.1359A>T p.R453S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.855); catalogued as COSV99839192; called by muse, mutect2, varscan2
- MKLN1 | c.1302A>T p.Q434H | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100759938; called by muse, mutect2, varscan2
- MKRN3 | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV100091431; called by muse, mutect2
- MMEL1 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99058868; called by muse, mutect2, varscan2
- MRC1 | c.115G>T p.V39L | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100509649; called by muse, mutect2, varscan2
- MROH2B | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV101270837, COSV68189552; called by muse, mutect2, varscan2
- MTRR | c.364G>A p.G122S (on ENST00000264668; = p.G95S on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52942123; called by muse, mutect2, varscan2
- MUC6 | c.4264G>C p.V1422L | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101424701; called by muse, mutect2, varscan2
- MYH1 | c.4536G>T p.E1512D | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56844829, COSV99876532; called by muse, mutect2, varscan2
- MYH1 | c.2761G>T p.A921S | Missense Mutation (SNP) | VAF 68/111 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs921701135, COSV56853133; called by muse, mutect2, varscan2
- MYH1 | c.2346T>A p.D782E | Missense Mutation (SNP) | VAF 76/98 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV56844671, COSV99876534; called by muse, mutect2, varscan2
- MYH13 | c.3563A>T p.Q1188L | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV99354829; called by muse, mutect2
- MYH8 | c.4265A>T p.Q1422L | Missense Mutation (SNP) | VAF 82/99 reads (83%) | SIFT tolerated (0.2); PolyPhen benign (0.285); catalogued as COSV101238552; called by muse, mutect2, varscan2
- NADK | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV100410993; called by muse, mutect2, varscan2
- NANOG | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV99981466, COSV99981680; called by muse, mutect2, varscan2
- NAP1L3 | c.976G>C p.G326R | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV100220152, COSV100220538; called by muse, mutect2, varscan2
- NAV3 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.726); catalogued as COSV99893702; called by muse, mutect2, varscan2
- NCL | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as rs1171986774, COSV100502424; called by muse, mutect2, varscan2
- NCOA6 | c.236-1G>A p.X79_splice | Splice Site (SNP) | VAF 21/66 reads (32%) | catalogued as COSV62861070; called by muse, mutect2, varscan2
- NDRG1 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100106298; called by muse, mutect2, varscan2
- NEB | c.18709C>A p.R6237S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV99425846; called by muse, mutect2, varscan2
- NEB | c.18708A>T p.K6236N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99425850; called by muse, mutect2, varscan2
- NECAB1 | c.977G>T p.S326I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.516); catalogued as rs1289157219, COSV101341145; called by muse, mutect2, varscan2
- NECAB2 | c.878C>A p.A293D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.929); catalogued as rs759775850, COSV104397250; called by muse, mutect2, varscan2
- NEU4 | c.736G>T p.G246C (on ENST00000391969 / NM_001167602.3; = p.G258C on NM_080741.4) | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1184021466, COSV100372152; called by mutect2, varscan2
- NLRP12 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV100144706; called by muse, mutect2, varscan2
- NOTCH1 | c.2014G>C p.G672R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53027530, COSV99490187, COSV99493594; called by muse, mutect2, varscan2
- NOTCH2 | c.4027C>T p.Q1343* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99865725; called by muse, mutect2, varscan2
- NPAP1 | c.906G>T p.M302I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.329); catalogued as rs1413225325, COSV100275780, COSV61504251; called by muse, mutect2, varscan2
- NPTXR | c.1040A>T p.N347I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396204676, COSV100285513; called by muse, mutect2, varscan2
- NPY2R | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs374458370; called by muse, mutect2, varscan2
- NRF1 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV99782014; called by muse, mutect2, varscan2
- NRG3 | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100932408; called by muse, mutect2, varscan2
- NUP205 | c.4342A>T p.M1448L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99607342; called by muse, mutect2, varscan2
- OR1D2 | c.652T>A p.Y218N | Missense Mutation (SNP) | VAF 48/58 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100513942; called by muse, mutect2, varscan2
- OR1S2 | c.409G>C p.V137L | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100224299; called by muse, mutect2, varscan2
- OR2T27 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.068); catalogued as COSV100788315, COSV61282469; called by muse, mutect2, varscan2
- OR2T6 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100861603; called by muse, mutect2, varscan2
- OR4K5 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 69/309 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV100262525, COSV60002621; called by muse, mutect2, varscan2
- OR4M1 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 78/371 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100271375; called by muse, mutect2, varscan2
- OR51F2 | c.782C>A p.S261Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771960979, COSV59066341; called by muse, mutect2, varscan2
- OR5A2 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV100119810; called by muse, mutect2, varscan2
- OR5B2 | c.481A>T p.I161L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV100222922; called by muse, mutect2, varscan2
- OR6C6 | c.311T>C p.L104S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.103); catalogued as rs751985604, COSV100626504; called by muse, mutect2, varscan2
- OR6K3 | c.229A>T p.N77Y (on ENST00000368146; = p.N61Y on NM_001005327.2) | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.147); catalogued as COSV100933873, COSV63746015; called by muse, mutect2, varscan2
- OR8D2 | c.632C>A p.T211K | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100659054; called by muse, mutect2, varscan2
- OR8G1 | c.632G>T p.S211I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.013); catalogued as rs1310367384; called by mutect2, varscan2
- OR8I2 | c.554C>A p.A185E | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV56169029; called by muse, mutect2, varscan2
- OR9I1 | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100110299; called by muse, mutect2, varscan2
- PCDH15 | c.4882C>A p.P1628T (on ENST00000644397 / NM_001354429.2; = p.P1570T on NM_001142771.2) | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64724931; called by muse, mutect2, varscan2
- PCDHB3 | c.1930G>C p.V644L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV99165960; called by muse, mutect2, varscan2
- PCNT | c.4406C>A p.S1469Y | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100855815; called by muse, mutect2, varscan2
- PDCD7 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs61756022, COSV52600490, COSV52601352; called by muse, mutect2, varscan2
- PDGFRA | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 83/134 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99957257; called by muse, mutect2, varscan2
- PDZD2 | c.308dup p.K104Qfs*38 | Frame Shift Ins (INS) | VAF 10/56 reads (18%) | catalogued as rs750970663; called by mutect2, varscan2
- PGK2 | c.920T>C p.I307T | Missense Mutation (SNP) | VAF 63/92 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100505611; called by muse, mutect2, varscan2
- PGLYRP3 | c.520C>G p.P174A | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.171); catalogued as COSV99319843; called by muse, mutect2, varscan2
- PIGA | c.1140A>G p.I380M | Missense Mutation (SNP) | VAF 191/216 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100363492; called by muse, mutect2, varscan2
- PIK3C2G | c.1801G>T p.V601L (on ENST00000676171; = p.V560L on NM_004570.5) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV99853019; called by mutect2, varscan2
- PKD1L1 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200343133, COSV56963991, COSV99221622; called by muse, mutect2, varscan2
- PKHD1 | c.6639C>G p.F2213L | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100583963; called by muse, mutect2, varscan2
- PLCH1 | c.2497G>T p.V833L (on ENST00000340059 / NM_001130960.2; = p.V845L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV100397719; called by muse, mutect2, varscan2
- PLXNA4 | c.4148G>T p.R1383L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100325938; called by muse, mutect2, varscan2
- PNMA5 | c.572T>A p.V191E | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100721684; called by muse, mutect2, varscan2
- POTEE | c.2333A>T p.N778I | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100388531; called by muse, mutect2, varscan2
- PRDM9 | c.565C>A p.H189N | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.391); catalogued as rs1261340959, COSV57007987, COSV99690862; called by muse, mutect2, varscan2
- PROSER3 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as rs778934458, COSV56554100, COSV99994643; called by muse, mutect2, varscan2
- PTGIR | c.366C>G p.S122R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs1280267256, COSV99355030; called by muse, mutect2, varscan2
- PTPRD | c.622G>C p.V208L | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100645924, COSV61970256; called by muse, mutect2, varscan2
- PTPRH | c.2047A>T p.N683Y | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99671272; called by muse, mutect2, varscan2
- PTPRR | c.756A>T p.K252N | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99318254; called by muse, mutect2, varscan2
- QSER1 | c.3944C>T p.S1315L (on ENST00000399302; = p.S1444L on NM_001076786.3) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs897775418, COSV101234936, COSV67900520; called by muse, mutect2, varscan2
- RBBP6 | c.4936A>G p.S1646G | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as COSV100154787; called by muse, mutect2, varscan2
- RBM15B | c.2529del p.S844Pfs*27 | Frame Shift Del (DEL) | VAF 21/37 reads (57%) | catalogued as rs781825075; called by mutect2, pindel, varscan2
- RGS7 | c.742C>A p.P248T | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.388); catalogued as COSV100469577; called by muse, mutect2, varscan2
- RGS7 | c.528-2A>G p.X176_splice | Splice Site (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100469582; called by muse, mutect2, varscan2
- RIF1 | c.2607A>G p.S869= | Splice Region (SNP) | VAF 15/38 reads (39%) | catalogued as rs1381547166, COSV99690935; called by muse, mutect2, varscan2
- RNF214 | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV100326846; called by muse, mutect2, varscan2
- ROS1 | c.3301T>G p.W1101G | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100877496; called by muse, mutect2, varscan2
- RP1 | c.1316A>C p.Q439P | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV99608317; called by muse, mutect2, varscan2
- RPS8 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as COSV63234356, COSV63234575; called by muse, mutect2, varscan2
- RTL4 | c.838T>C p.C280R | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100466060; called by muse, mutect2, varscan2
- RUNX1T1 | c.21C>A p.N7K | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1033444360, COSV99753631; called by muse, mutect2, varscan2
- SAMD7 | c.999C>A p.H333Q | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100157017; called by muse, mutect2, varscan2
- SCG2 | c.1577G>T p.R526L | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1412043621, COSV100544835; called by muse, mutect2, varscan2
- SCIN | c.1765T>A p.F589I (on ENST00000297029 / NM_001112706.3; = p.F342I on NM_033128.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99765071; called by muse, mutect2
- SCN11A | c.4876T>C p.F1626L | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1269070964, COSV100182069, COSV56573597; called by muse, mutect2, varscan2
- SCN1A | c.5326G>T p.V1776F (on ENST00000303395 / NM_001202435.3; = p.V1765F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100321309; called by muse, mutect2, varscan2
- SCN1A | c.2435C>A p.T812K (on ENST00000303395 / NM_001202435.3; = p.T801K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as CM068493, CM113297, COSV100321312; called by muse, mutect2, varscan2
- SCN1A | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.108); catalogued as COSV100321315; called by muse, mutect2, varscan2
- SCN5A | c.2752G>T p.V918F | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as rs1177134349, COSV100349677; called by muse, mutect2
- SECTM1 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs745434411, COSV99486316; called by muse, mutect2, varscan2
- SERPINA4 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs758792521, COSV100097362; called by muse, mutect2, varscan2
- SERPINB5 | c.163G>T p.G55* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV101237679; called by muse, mutect2, varscan2
- SERPINB5 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs753774243, COSV101237680; called by muse, mutect2, varscan2
- SH3YL1 | c.914A>G p.Q305R | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV100642191; called by muse, mutect2, varscan2
- SI | c.721A>C p.I241L | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100016516; called by muse, mutect2, varscan2
- SIGLEC12 | c.954C>A p.D318E (on ENST00000291707 / NM_053003.4; = p.D200E on NM_033329.2) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as rs1460847558, COSV99389499; called by muse, mutect2, varscan2
- SIGLEC14 | c.713A>T p.N238I | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV99707747; called by muse, mutect2, varscan2
- SIRT2 | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV99979518; called by muse, mutect2, varscan2
- SLC18A2 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.34); catalogued as COSV100041881; called by muse, mutect2, varscan2
- SLC22A10 | c.1178G>T p.R393L | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as COSV100235929, COSV60420016; called by muse, mutect2, varscan2
- SLC45A2 | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99672954; called by muse, mutect2, varscan2
- SLC46A2 | c.698T>G p.V233G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV100953489; called by muse, mutect2, varscan2
- SLC5A6 | c.1349G>T p.C450F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100143447; called by muse, mutect2, varscan2
- SLC6A18 | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57253196; called by mutect2, varscan2
- SLITRK5 | c.763T>A p.Y255N | Missense Mutation (SNP) | VAF 73/107 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100281016; called by muse, mutect2, varscan2
- SMPD4 | c.1933G>A p.E645K (on ENST00000409031 / NM_017951.4; = p.E616K on NM_017751.4) | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs924505708, COSV100302630; called by muse, mutect2, varscan2
- SMYD1 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101352480; called by muse, mutect2
- SOWAHB | c.1945G>T p.D649Y | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100530759; called by muse, mutect2, varscan2
- SOWAHB | c.1944G>T p.Q648H | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100530760; called by muse, mutect2, varscan2
- SPTA1 | c.6442G>T p.E2148* | Nonsense Mutation (SNP) | VAF 39/101 reads (39%) | catalogued as COSV100935289, COSV63751568; called by muse, mutect2, varscan2
- SPTA1 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs765819340, COSV100935290; called by muse, mutect2, varscan2
- STEAP2 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.856); catalogued as COSV99840571; called by muse, mutect2, varscan2
- SYT9 | c.528G>C p.L176F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1401738243, COSV100608728; called by muse, mutect2, varscan2
- TAB3 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 79/96 reads (82%) | SIFT tolerated (0.42); PolyPhen benign (0.131); catalogued as COSV55836356; called by muse, mutect2, varscan2
- TAS2R41 | c.513G>T p.K171N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV101281507; called by muse, mutect2, varscan2
- TBC1D32 | c.2548C>A p.Q850K | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs1426610075, COSV99250864; called by muse, mutect2, varscan2
- TEKT4 | c.1192A>G p.M398V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV99726565; called by muse, mutect2, varscan2
- TELO2 | c.1561+1G>T p.X521_splice | Splice Site (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99248560; called by muse, mutect2, varscan2
- TESC | c.223G>T p.G75* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV58812201, COSV58813665; called by muse, mutect2, varscan2
- TESMIN | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1169669206, COSV99663847; called by muse, mutect2
- TGM6 | c.2104G>A p.V702M | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99172043; called by muse, mutect2, varscan2
- THSD7A | c.2717A>G p.D906G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101448819; called by muse, mutect2, varscan2
- THSD7B | c.2350T>C p.Y784H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV99755322; called by muse, mutect2, varscan2
- TMEM163 | c.421A>T p.N141Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99926781; called by muse, mutect2, varscan2
- TMEM171 | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490489865, COSV99825043; called by muse, mutect2, varscan2
- TMPRSS11A | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.094); catalogued as COSV100602768; called by muse, mutect2, varscan2
- TNN | c.2066G>T p.W689L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as rs1387731816, COSV99512559; called by muse, mutect2, varscan2
- TNN | c.2067G>C p.W689C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs956340915, COSV99512561; called by muse, mutect2, varscan2
- TNR | c.2221C>A p.L741I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99690676; called by muse, mutect2, varscan2
- TRDN | c.127A>T p.T43S | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100522913; called by muse, mutect2, varscan2
- TRHDE | c.2587C>A p.L863I | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.756); catalogued as COSV99671778; called by muse, mutect2, varscan2
- TRIM26 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs773245215, COSV70982647; called by muse, mutect2, varscan2
- TRIM67 | c.1557G>C p.Q519H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as COSV100792175; called by muse, mutect2, varscan2
- TRMT1L | c.1993G>T p.V665L | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100834694; called by muse, mutect2, varscan2
- TRPC3 | c.789C>A p.H263Q (on ENST00000379645 / NM_001366479.2; = p.H190Q on NM_003305.2) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53382873, COSV99313154; called by muse, mutect2, varscan2
- TSHZ2 | c.1738C>A p.P580T | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100296513; called by muse, mutect2, varscan2
- TTN | c.75790G>A p.G25264S (on ENST00000591111; = p.G17840S on NM_003319.4) | Missense Mutation (SNP) | VAF 36/104 reads (35%) | PolyPhen possibly damaging (0.878); catalogued as rs772844758, COSV100622722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.63991C>A p.L21331I (on ENST00000591111; = p.L13907I on NM_003319.4) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | PolyPhen benign (0.02); catalogued as COSV100606978, COSV59914687; called by muse, mutect2, varscan2
- TTN | c.15233A>T p.K5078I (on ENST00000591111; = p.K4151I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | PolyPhen benign (0.045); catalogued as COSV100622727; called by muse, mutect2, varscan2
- ULBP2 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT tolerated (0.39); PolyPhen benign (0.196); catalogued as COSV66265429; called by muse, mutect2, varscan2
- ULBP2 | c.631+1G>T p.X211_splice | Splice Site (SNP) | VAF 50/69 reads (72%) | catalogued as rs1189461794, COSV100951257; called by muse, mutect2, varscan2
- USP13 | c.760T>C p.Y254H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); catalogued as COSV99831524; called by muse, mutect2, varscan2
- USP24 | c.7805C>T p.S2602L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as COSV99600477; called by muse, mutect2, varscan2
- UTP25 | c.1850A>G p.Y617C | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs561252969, COSV101504759; called by muse, mutect2, varscan2
- VRTN | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); catalogued as rs547847712, COSV99832367; called by muse, mutect2, varscan2
- XKR4 | c.959T>G p.L320R | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100533413; called by muse, varscan2
- XKR4 | c.1592C>G p.P531R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.564); catalogued as COSV100533414; called by muse, mutect2, varscan2
- ZBBX | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 56/181 reads (31%) | catalogued as rs1177995125, COSV100284577; called by muse, mutect2, varscan2
- ZBTB16 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100251850; called by muse, mutect2, varscan2
- ZBTB37 | c.335A>T p.Q112L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV100774619; called by muse, mutect2, varscan2
- ZFHX4 | c.3851C>A p.P1284H | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as rs754242345, COSV99265653; called by muse, varscan2
- ZNF141 | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV99549901; called by muse, mutect2, varscan2
- ZNF175 | c.2080A>G p.T694A | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs1243871799, COSV99219657; called by muse, mutect2, varscan2
- ZNF215 | c.520A>T p.S174C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99549807; called by muse, mutect2, varscan2
- ZNF254 | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100741580, COSV100741729; called by muse, mutect2, varscan2
- ZNF382 | c.1313G>T p.C438F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250964191, COSV53087968; called by muse, mutect2, varscan2
- ZNF804B | c.3770C>A p.P1257H | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100305035; called by muse, mutect2, varscan2
- ADCY1 | c.860del p.P287Lfs*16 | Frame Shift Del (DEL) | VAF 46/131 reads (35%) | called by mutect2, pindel, varscan2
- AGO2 | c.1715del p.G572Efs*3 | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- CD200 | c.769+1del | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- FBXL20 | c.898del p.E300Nfs*13 | Frame Shift Del (DEL) | VAF 91/172 reads (53%) | called by mutect2, pindel, varscan2
- FXYD4 | c.65del p.P22Hfs*18 | Frame Shift Del (DEL) | VAF 42/95 reads (44%) | called by mutect2, pindel, varscan2
- GPR139 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACF1 | c.20095del p.D6699Mfs*20 (on ENST00000372915; = p.D4744Mfs*20 on NM_012090.5) | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel
- OR8G1 | c.631dup p.S211Kfs*22 | Frame Shift Ins (INS) | VAF 24/68 reads (35%) | called by mutect2, varscan2
- SPHKAP | c.326del p.P109Qfs*10 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- TNXB | c.8159_8160del p.R2720Qfs*63 (on ENST00000647633; = p.R2473Qfs*63 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 29/57 reads (51%) | called by pindel, varscan2
- TPTE | c.1613G>T p.G538V (on ENST00000618007 / NM_199261.4; = p.G520V on NM_199259.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- ABCB5 | c.2397C>A p.A799= (on ENST00000404938 / NM_001163941.2; = p.A354= on NM_178559.6) | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV99327535; called by muse, mutect2, varscan2
- ACTN2 | c.2232G>T p.T744= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs144676770; called by muse, mutect2, varscan2
- ADAMTS20 | c.2973T>A p.S991= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV101166083, COSV101166359; called by muse, mutect2, varscan2
- ADCY3 | c.2271G>C p.V757= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99568798; called by muse, mutect2, varscan2
- AKAP9 | c.11703A>G p.T3901= (on ENST00000359028; = p.T3877= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV99134012; called by muse, mutect2, varscan2
- AMDHD1 | c.819G>T p.G273= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99900428; called by muse, mutect2
- ANKRD50 | c.1359A>G p.Q453= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as rs771312306, COSV101539005; called by muse, mutect2, varscan2
- ANXA5 | c.582T>C p.F194= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs1347745926, COSV99634580; called by muse, mutect2, varscan2
- ARHGEF10L | c.795G>T p.V265= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV99393445; called by muse, mutect2, varscan2
- ARSG | c.1314G>A p.R438= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100048545; called by muse, mutect2, varscan2
- ASTN2 | c.1827C>A p.S609= (on ENST00000313400 / NM_001365069.1; = p.S558= on NM_014010.5) | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV100529173; called by muse, mutect2, varscan2
- BOC | c.720C>T p.I240= | Silent (SNP) | VAF 53/183 reads (29%) | catalogued as COSV56348554; called by muse, mutect2, varscan2
- BRD1 | c.1017C>T p.I339= | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as COSV53458494; called by muse, mutect2
- C19orf54 | c.918G>C p.R306= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs1232011784, COSV99648964; called by muse, mutect2, varscan2
- C2CD3 | c.3849A>T p.L1283= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV100487126; called by muse, mutect2, varscan2
- CACNA1H | c.7014C>T p.S2338= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs1178477717, COSV99326930; called by muse, mutect2, varscan2
- CADPS2 | c.1089G>T p.L363= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV100463403, COSV57367074; called by muse, mutect2, varscan2
- CATSPERD | c.1125G>C p.A375= | Silent (SNP) | VAF 34/52 reads (65%) | catalogued as COSV100486922; called by muse, mutect2, varscan2
- CDCA7 | c.879A>T p.R293= (on ENST00000347703 / NM_145810.3; = p.R372= on NM_031942.5) | Silent (SNP) | VAF 55/133 reads (41%) | catalogued as COSV100143678; called by muse, mutect2, varscan2
- CENPE | c.7347A>T p.G2449= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99478633; called by muse, mutect2
- CNTLN | c.1479C>T p.S493= | Silent (SNP) | VAF 42/60 reads (70%) | catalogued as COSV99265090; called by muse, mutect2, varscan2
- CNTN5 | c.2820A>G p.L940= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1319357109, COSV99679455; called by muse, mutect2, varscan2
- CNTNAP5 | c.2662C>T p.L888= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV101443864; called by muse, mutect2, varscan2
- COL20A1 | c.1167C>A p.T389= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV100491002; called by muse, mutect2, varscan2
- COL9A3 | c.1021C>A p.R341= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100673254, COSV100673516; called by muse, mutect2, varscan2
- COPS6 | c.324G>A p.K108= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs1489262059, COSV100385067; called by muse, mutect2, varscan2
- CSMD2 | c.3651C>G p.P1217= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99593068; called by muse, mutect2
- CXorf21 | c.264C>A p.P88= | Silent (SNP) | VAF 163/190 reads (86%) | catalogued as COSV66762461; called by muse, mutect2, varscan2
- DCAF12L2 | c.195A>T p.P65= | Silent (SNP) | VAF 20/25 reads (80%) | catalogued as COSV100758737; called by muse, mutect2, varscan2
- DCAF4L2 | c.432G>C p.L144= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV60479877; called by muse, mutect2, varscan2
- DDX60 | c.4122G>C p.L1374= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV101190564; called by muse, mutect2, varscan2
- DGKG | c.1926G>T p.G642= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs561957681, COSV99403940; called by muse, mutect2, varscan2
- DRC1 | c.786C>A p.R262= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV99985584; called by muse, mutect2, varscan2
- DRC1 | c.1725G>T p.A575= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV55521185, COSV99718394; called by muse, mutect2, varscan2
- EDC4 | c.201G>T p.R67= | Silent (SNP) | VAF 90/155 reads (58%) | catalogued as COSV99534533; called by muse, mutect2, varscan2
- ERICH3 | c.3078G>A p.K1026= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV100445089; called by muse, mutect2, varscan2
- ERN2 | c.123G>T p.L41= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99891987; called by muse, mutect2, varscan2
- ESX1 | c.636C>A p.A212= | Silent (SNP) | VAF 60/87 reads (69%) | catalogued as COSV101006488; called by muse, mutect2, varscan2
- FAR2 | c.1035C>T p.N345= | Silent (SNP) | VAF 83/243 reads (34%) | catalogued as rs1382702551, COSV99479438; called by muse, mutect2, varscan2
- FAT4 | c.14454G>A p.E4818= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV100629434; called by muse, mutect2, varscan2
- FCRLA | c.1128C>A p.T376= (on ENST00000367959; = p.T353= on NM_032738.4) | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs774844832, COSV99376414; called by muse, mutect2, varscan2
- FOXP2 | c.1747C>A p.R583= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100647133, COSV104416907; called by muse, mutect2, varscan2
- GLDN | c.378G>A p.V126= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as COSV100117918; called by muse, mutect2, varscan2
- GLI3 | c.1383C>T p.V461= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV101229961; called by muse, mutect2, varscan2
- GPR25 | c.726G>T p.S242= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs1294463822, COSV58498341, COSV58499242; called by muse, mutect2, varscan2
- IGKV1-16 | c.237G>T p.G79= | Silent (SNP) | VAF 76/211 reads (36%) | catalogued as rs773728199; called by muse, mutect2, varscan2
- IGSF11 | c.156C>G p.L52= (on ENST00000393775 / NM_001015887.3; = p.L51= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 86/177 reads (49%) | catalogued as COSV100677647; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1278A>G p.E426= (on ENST00000485419 / NM_001197113.1; = p.E350= on NM_014575.3) | Silent (SNP) | VAF 86/279 reads (31%) | catalogued as COSV100541565; called by muse, mutect2, varscan2
- KCNA3 | c.1374G>A p.K458= | Silent (SNP) | VAF 33/55 reads (60%) | catalogued as COSV100871285; called by muse, mutect2, varscan2
- KCNH7 | c.2088G>C p.L696= | Silent (SNP) | VAF 77/193 reads (40%) | catalogued as COSV100037015; called by muse, mutect2, varscan2
- KLRC1 | c.360T>A p.P120= | Silent (SNP) | VAF 84/229 reads (37%) | catalogued as COSV100760856; called by muse, mutect2, varscan2
- KRIT1 | c.168G>T p.T56= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100388866; called by muse, mutect2, varscan2
- LRP2 | c.4071T>C p.N1357= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs1179328716, COSV99789606; called by muse, mutect2, varscan2
- MARCO | c.1294C>A p.R432= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as COSV100503674, COSV100503881, COSV59054917; called by muse, mutect2, varscan2
- MDN1 | c.11334G>A p.E3778= | Silent (SNP) | VAF 49/199 reads (25%) | catalogued as COSV101021626; called by muse, mutect2, varscan2
- MFSD2A | c.483G>T p.L161= (on ENST00000372809 / NM_001136493.3; = p.L148= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100861720; called by muse, mutect2, varscan2
- MFSD2A | c.832C>A p.R278= (on ENST00000372809 / NM_001136493.3; = p.R265= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as rs751477861, COSV100861722; called by muse, mutect2, varscan2
- MKI67 | c.843G>A p.Q281= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV100896847; called by muse, mutect2, varscan2
- MLF2 | c.723A>T p.R241= | Silent (SNP) | VAF 49/111 reads (44%) | catalogued as rs766940272, COSV99180108; called by muse, mutect2, varscan2
- MOS | c.765C>T p.G255= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV61337127; called by muse, mutect2, varscan2
- MRPL14 | c.336G>T p.G112= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV100921048; called by muse, mutect2, varscan2
- MSL2 | c.315A>G p.K105= | Silent (SNP) | VAF 27/228 reads (12%) | catalogued as COSV99387822; called by muse, mutect2, varscan2
- MYH13 | c.546G>A p.G182= | Silent (SNP) | VAF 66/75 reads (88%) | catalogued as rs1233482902, COSV99354835; called by muse, mutect2, varscan2
- NAV3 | c.5808A>G p.A1936= (on ENST00000397909 / NM_001024383.2; = p.A1914= on NM_014903.6) | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs911997542, COSV57084141; called by muse, mutect2, varscan2
- NHLH2 | c.360C>T p.R120= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs765713385, COSV100205021; called by muse, mutect2, varscan2
- NPFFR2 | c.165G>T p.A55= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs964145682, COSV100441038; called by muse, mutect2, varscan2
- OCA2 | c.2361G>T p.A787= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV100668269; called by muse, mutect2, varscan2
- OPA1 | c.861C>T p.I287= (on ENST00000361510 / NM_130837.3; = p.I232= on NM_015560.3) | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as COSV100655407; called by muse, mutect2, varscan2
- OR2A12 | c.427C>T p.L143= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as COSV101283187; called by muse, mutect2, varscan2
- OR52K2 | c.441C>G p.G147= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV100355796; called by muse, mutect2, varscan2
- OR8B8 | c.78C>A p.P26= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100045163, COSV60145985; called by muse, mutect2, varscan2
- OR8D4 | c.720C>T p.T240= | Silent (SNP) | VAF 55/137 reads (40%) | catalogued as rs1185143135, COSV100361889; called by muse, mutect2, varscan2
- OR8J3 | c.747G>T p.T249= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV56880098, COSV56881389; called by muse, mutect2, varscan2
- PAH | c.526C>A p.R176= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as CM930541, COSV100188294; called by muse, mutect2, varscan2
- PCDH10 | c.564A>T p.P188= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs1197775104, COSV99994135; called by muse, mutect2, varscan2
- POFUT1 | c.1110G>T p.G370= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV101003330; called by muse, mutect2, varscan2
- PPP1R13L | c.2109C>T p.C703= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV100714842; called by muse, mutect2, varscan2
- PRDX6 | c.390A>G p.T130= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV100458455, COSV100458534; called by muse, mutect2, varscan2
- PREX2 | c.3624G>C p.L1208= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV99908802; called by muse, mutect2, varscan2
- PRG2 | c.438G>A p.Q146= | Silent (SNP) | VAF 75/168 reads (45%) | catalogued as COSV100314988; called by muse, mutect2, varscan2
- PRL | c.417T>A p.A139= | Silent (SNP) | VAF 30/44 reads (68%) | catalogued as COSV100123118; called by muse, mutect2, varscan2
- PRM2 | c.6C>A p.V2= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs761412914, COSV54113213, COSV99617756; called by muse, mutect2, varscan2
- PUS10 | c.276T>A p.S92= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100369681; called by muse, mutect2, varscan2
- SCN3A | c.3405A>G p.A1135= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV99327781; called by muse, mutect2, varscan2
- SDK1 | c.2559G>T p.L853= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV101269638; called by muse, mutect2, varscan2
- SESN3 | c.882G>A p.K294= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV99565844; called by muse, mutect2, varscan2
- SLC30A3 | c.933G>T p.S311= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV99273777, COSV99273918; called by muse, mutect2, varscan2
- SLC5A1 | c.261G>T p.L87= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99833623; called by muse, mutect2, varscan2
- SLITRK3 | c.2139A>T p.G713= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV99579721; called by muse, mutect2, varscan2
- SPAM1 | c.1236T>C p.G412= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as COSV99773266; called by muse, mutect2, varscan2
- SPON1 | c.1134C>A p.P378= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100116403; called by muse, mutect2, varscan2
- STK36 | c.3213G>T p.L1071= | Silent (SNP) | VAF 68/167 reads (41%) | catalogued as COSV99831717; called by muse, mutect2, varscan2
- STK4 | c.1080G>T p.T360= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100860360, COSV65672032; called by muse, mutect2, varscan2
- TENM3 | c.1740C>A p.T580= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs1202059420, COSV101305306; called by muse, mutect2, varscan2
- TIRAP | c.267C>T p.C89= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs200442139, COSV101201659; called by muse, varscan2
- TNPO3 | c.1389A>T p.L463= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as COSV99603251; called by muse, mutect2, varscan2
- TOGARAM1 | c.705A>T p.A235= | Silent (SNP) | VAF 59/78 reads (76%) | catalogued as COSV100753203; called by muse, mutect2, varscan2
- TOPORS | c.3081A>T p.P1027= | Silent (SNP) | VAF 41/63 reads (65%) | catalogued as COSV100859561; called by muse, mutect2, varscan2
- TRMT6 | c.546C>T p.H182= | Silent (SNP) | VAF 43/158 reads (27%) | catalogued as rs752056178, COSV99177591; called by muse, mutect2, varscan2
- UBQLN1 | c.1734A>C p.A578= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV99973484; called by muse, mutect2, varscan2
- XKR4 | c.822A>T p.I274= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as COSV59319271; called by muse, varscan2
- ZFHX4 | c.8259A>C p.S2753= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99265657; called by muse, mutect2, varscan2
- ZFYVE9 | c.3012G>T p.R1004= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV99820442; called by muse, mutect2, varscan2
- ZNF574 | c.678G>T p.P226= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV99726339; called by muse, mutect2, varscan2
- ZNF691 | c.300G>T p.G100= (on ENST00000372502; = p.G69= on NM_015911.3) | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as COSV100996115; called by muse, mutect2, varscan2
- BIRC8 | n.1431G>T | RNA (SNP) | VAF 37/110 reads (34%) | catalogued as COSV101461352; called by muse, mutect2, varscan2
- DNM2 | c.1336-1042A>G | Intron (SNP) | VAF 26/36 reads (72%) | catalogued as COSV100117668; called by muse, mutect2, varscan2
- FOLH1B | n.1209C>T | RNA (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- IKBIP | c.297+8140A>G | Intron (SNP) | VAF 25/44 reads (57%) | catalogued as COSV100141860; called by muse, mutect2, varscan2
- MAP3K19 | c.3222+480del | Intron (DEL) | VAF 39/115 reads (34%) | called by mutect2, pindel, varscan2
- OR3A4P | n.620G>T | RNA (SNP) | VAF 40/58 reads (69%) | called by muse, mutect2
- SNORD116-25 | n.72C>A | RNA (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
